Somatic mutation profile of tumor specimen BA2532D (aliquot aq-BA2532D) from BEATAML1.0 case 2323, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.2 years (15,431 days).
Specimen BA2532D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a7cbbf-2318-4d6b-9ae4-26299aba6c7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2243D (Solid Tissue Normal), aliquot aq-BA2243D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93d8c7c8-782b-4d98-beec-7b105b9096ae

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SAMD7 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV59419288; called by muse, mutect2
- VPS8 | c.2432G>A p.R811Q (on ENST00000625842 / NM_001349294.1; = p.R809Q on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs1349274224; called by muse, mutect2, varscan2
- NELFE | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2
- PTPRK | c.3858G>T p.W1286C (on ENST00000368215 / NM_001291984.2; = p.W1287C on NM_002844.4) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TANC2 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, varscan2
- ZFHX3 | c.4217G>T p.C1406F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NRP2 | c.1353C>T p.S451= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs1021437408; called by muse, varscan2
